CCDI case PBBUGH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d23792db-bff7-4e20-aa84-b931c642720c

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.0 years (4,370 days).

Biospecimens (3 samples)
- Sample 0DHDZE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHDZR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHE04: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
